CCDI case PBCESL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b4dd67f9-f5b7-400c-b2a1-9647b8a92420

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.0 years (3,304 days).

Biospecimens (3 samples)
- Sample 0DQ7WE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
